Somatic mutation profile of tumor specimen 0DEHNW from CCDI case PBBPJV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Eyelid; Age at diagnosis: 6.1 years (2,241 days).
Specimen 0DEHNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db61f9f-8de3-4e89-983a-268200cfc168.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHMY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c05bee5-1c58-4fdb-ad31-083a724c9e5d

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JHY | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 128/398 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV57073940; called by muse, varscan2
- MACF1 | c.20476G>A p.A6826T (on ENST00000372915; = p.A4871T on NM_012090.5) | Missense Mutation (SNP) | VAF 174/565 reads (31%) | catalogued as COSV57119585; called by muse, varscan2
- MUC17 | c.9754C>T p.P3252S | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs1562817011; called by muse, varscan2
- MUC17 | c.9755C>T p.P3252L | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs141936845, COSV60282187; called by muse, varscan2
- PCDH15 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 186/606 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1281151581, COSV57287031; called by muse, varscan2
- RC3H1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1160885450, COSV51197862; called by muse, varscan2
- RUNX3 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58246304; called by muse, varscan2
- SYNPO2L | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1267256034; called by muse, varscan2
- ADAM22 | c.1569T>G p.C523W | Missense Mutation (SNP) | VAF 102/526 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C1orf146 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 122/588 reads (21%) | called by muse, varscan2
- MUC16 | c.6163C>T p.L2055F | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- PDHA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, varscan2
- PRKCQ | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 116/440 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, varscan2
- RAD21L1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 90/352 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, varscan2
- SRCAP | c.5966C>T p.S1989F | Missense Mutation (SNP) | VAF 129/604 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- LRP1B | c.4839C>T p.F1613= | Silent (SNP) | VAF 205/636 reads (32%) | catalogued as rs766034085, COSV67188754, COSV67242118; called by muse, varscan2
- NHSL1 | c.1251C>T p.I417= | Silent (SNP) | VAF 144/431 reads (33%) | called by muse, varscan2
- TMEM145 | c.558C>T p.F186= | Silent (SNP) | VAF 110/458 reads (24%) | catalogued as COSV56623939; called by muse, varscan2
- EIF1B-AS1 | n.536+6400C>T | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, varscan2
- FCRL5 | c.*56G>A | 3'UTR (SNP) | VAF 214/881 reads (24%) | called by muse, varscan2
- LAMA1 | c.6775-36A>G | Intron (SNP) | VAF 104/265 reads (39%) | called by muse, varscan2
- MSH4 | c.*36G>C | 3'UTR (SNP) | VAF 70/260 reads (27%) | called by muse, varscan2
- SLC25A13 | c.1019-17A>T | Intron (SNP) | VAF 99/292 reads (34%) | called by muse, varscan2
